Somatic mutation profile of tumor specimen C3L-03678-02 (aliquot CPT0190550006) from CPTAC case C3L-03678, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 49.9 years (18,220 days).
Specimen C3L-03678-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) deb16d2f-a981-40ca-8aa2-c9d404c99fda.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-03678-31 (Blood Derived Normal), aliquot CPT0191230002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a5e5975f-7375-4d64-8a7f-f6e3628552f0

The open-access MAF lists 544 somatic variants for this specimen: 379 protein-altering or splice-affecting, 106 silent, 59 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 318, Silent 106, Intron 30, Nonsense Mutation 27, 3'UTR 11, Splice Region 11, RNA 9, Frame Shift Del 8, Splice Site 8, Frame Shift Ins 5, 5'Flank 4, 5'UTR 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 67/392 reads (17%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NF1 | c.1381C>T p.R461* | Nonsense Mutation (SNP) | VAF 94/546 reads (17%) | hotspot (GDC flag); catalogued as rs878853865, CM000780, COSV62194747; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PRKN | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 80/544 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as rs772786691, CM030922; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA2 | c.6521C>T p.T2174M (on ENST00000614293; = p.T2144M on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/305 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as COSV99688123; called by muse, mutect2, varscan2
- AC006059.2 | c.918G>T p.L306F | Missense Mutation (SNP) | VAF 37/178 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs1417064093; called by muse, mutect2, varscan2
- ACAP1 | c.649C>G p.R217G | Missense Mutation (SNP) | VAF 102/302 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.552); catalogued as rs1567629594, COSV50139460; called by muse, mutect2, varscan2
- ACP4 | c.812C>T p.S271F | Missense Mutation (SNP) | VAF 83/539 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54516143; called by muse, mutect2, varscan2
- ADAMTS12 | c.3103C>G p.P1035A | Missense Mutation (SNP) | VAF 97/301 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.057); catalogued as COSV61264378; called by muse, mutect2, varscan2
- ALLC | c.266G>C p.R89P | Missense Mutation (SNP) | VAF 66/233 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as rs761437342; called by muse, mutect2, varscan2
- ANGPTL1 | c.237G>A p.M79I | Missense Mutation (SNP) | VAF 58/291 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.112); catalogued as rs1294754144; called by muse, mutect2, varscan2
- ANKFN1 | c.628C>T p.R210* | Nonsense Mutation (SNP) | VAF 106/425 reads (25%) | catalogued as rs376484390; called by muse, mutect2, varscan2
- APOB | c.97G>T p.E33* | Nonsense Mutation (SNP) | VAF 128/570 reads (22%) | catalogued as COSV51951265; called by muse, mutect2, varscan2
- ATP8B4 | c.1507G>T p.A503S | Missense Mutation (SNP) | VAF 31/168 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV52712160; called by muse, mutect2, varscan2
- BRINP3 | c.2152C>T p.Q718* | Nonsense Mutation (SNP) | VAF 41/176 reads (23%) | catalogued as COSV66542313; called by muse, mutect2, varscan2
- C10orf95 | c.268G>A p.A90T | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs1565243956; called by muse, mutect2
- CAMK2A | c.1120G>C p.D374H (on ENST00000348628 / NM_171825.2; = p.D385H on NM_015981.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/197 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV62245757, COSV62246315; called by muse, mutect2, varscan2
- CFAP58 | c.2585G>T p.G862V | Missense Mutation (SNP) | VAF 50/229 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63832696, COSV63834484; called by muse, mutect2, varscan2
- CLDND1 | c.317G>T p.C106F | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as rs1413331470; called by muse, mutect2, varscan2
- CLEC1A | c.789G>T p.M263I | Missense Mutation (SNP) | VAF 62/203 reads (31%) | SIFT tolerated (0.4); PolyPhen benign (0.01); catalogued as COSV59533372; called by muse, mutect2, varscan2
- CLRN2 | c.219G>C p.Q73H | Missense Mutation (SNP) | VAF 38/169 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.944); catalogued as rs774961807; called by muse, mutect2
- COL12A1 | c.1517C>T p.A506V | Missense Mutation (SNP) | VAF 104/290 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs189762594; called by muse, mutect2, varscan2
- COL25A1 | c.1090C>G p.R364G | Missense Mutation (SNP) | VAF 43/227 reads (19%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.995); catalogued as COSV67651331; called by muse, mutect2, varscan2
- COL6A5 | c.2075C>G p.S692C | Missense Mutation (SNP) | VAF 30/193 reads (16%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.935); catalogued as COSV55204598; called by muse, mutect2, varscan2
- CYFIP2 | c.1568G>T p.G523V | Missense Mutation (SNP) | VAF 43/165 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV100556936; called by muse, mutect2, varscan2
- DAB2IP | c.2015G>A p.G672D (on ENST00000408936; = p.G644D on NM_032552.3) | Missense Mutation (SNP) | VAF 90/252 reads (36%) | SIFT tolerated (0.57); PolyPhen benign (0.134); catalogued as rs1452805500; called by muse, mutect2, varscan2
- DCLRE1C | c.175C>G p.L59V | Missense Mutation (SNP) | VAF 59/360 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV63182047; called by muse, mutect2, varscan2
- DDX24 | c.1424G>A p.R475Q | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs373668422; called by muse, mutect2, varscan2
- DMKN | c.515G>A p.W172* | Nonsense Mutation (SNP) | VAF 114/480 reads (24%) | catalogued as COSV100304005; called by muse, mutect2, varscan2
- DNAH5 | c.6071A>T p.Q2024L | Missense Mutation (SNP) | VAF 100/397 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1161184929; called by muse, mutect2, varscan2
- DYRK1B | c.1111G>C p.G371R | Missense Mutation (SNP) | VAF 33/132 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.196); catalogued as rs1335875822; called by muse, mutect2, varscan2
- DYSF | c.4178G>C p.R1393T | Missense Mutation (SNP) | VAF 10/228 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.201); catalogued as COSV99244087; called by muse, mutect2
- EPRS1 | c.1649T>C p.V550A | Missense Mutation (SNP) | VAF 51/211 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.559); catalogued as rs1251743132; called by muse, mutect2, varscan2
- FAM184B | c.1080G>C p.E360D | Missense Mutation (SNP) | VAF 37/261 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.225); catalogued as rs373266922; called by muse, mutect2, varscan2
- FAM71B | c.1524G>T p.E508D | Missense Mutation (SNP) | VAF 62/307 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.07); catalogued as COSV100261822; called by muse, mutect2, varscan2
- FCRLB | c.606G>A p.M202I | Missense Mutation (SNP) | VAF 11/205 reads (5%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV100396415; called by muse, mutect2
- FOXO3 | c.1174G>T p.D392Y | Missense Mutation (SNP) | VAF 9/196 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV59626507; called by muse, mutect2
- FSIP2 | c.18716C>A p.P6239H | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV58089060; called by muse, mutect2, varscan2
- GABRA5 | c.614G>C p.W205S | Missense Mutation (SNP) | VAF 70/405 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59479151, COSV59482663; called by muse, mutect2
- GABRA5 | c.615G>T p.W205C | Missense Mutation (SNP) | VAF 71/402 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59481881; called by muse, mutect2
- GABRG2 | c.499A>G p.N167D | Missense Mutation (SNP) | VAF 12/224 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100729654; called by muse, mutect2
- GBA3 | c.787G>T p.D263Y | Missense Mutation (SNP) | VAF 32/220 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV72438311; called by muse, mutect2, varscan2
- HERC6 | c.1198C>A p.H400N | Missense Mutation (SNP) | VAF 10/181 reads (6%) | SIFT tolerated (0.33); PolyPhen benign (0.01); catalogued as COSV52032684; called by muse, mutect2
- HMX1 | c.995C>G p.P332R | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV68772027; called by muse, mutect2, varscan2
- IL17REL | c.767A>G p.H256R | Missense Mutation (SNP) | VAF 36/124 reads (29%) | SIFT tolerated (0.85); PolyPhen benign (0.001); catalogued as rs372492027; called by muse, mutect2, varscan2
- KCNH4 | c.646C>G p.R216G | Missense Mutation (SNP) | VAF 88/343 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.326); catalogued as COSV52920198, COSV52920317; called by muse, mutect2, varscan2
- KDM6A | c.564G>T p.K188N | Missense Mutation (SNP) | VAF 86/158 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV65038103; called by muse, mutect2, varscan2
- KIAA0319L | c.2398G>A p.V800I | Missense Mutation (SNP) | VAF 18/234 reads (8%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); catalogued as rs150251578; called by muse, mutect2
- KMT2E | c.3236C>A p.S1079* | Nonsense Mutation (SNP) | VAF 49/379 reads (13%) | catalogued as COSV57578777, COSV99996803, COSV99997164; called by muse, mutect2, varscan2
- KRT3 | c.1420G>C p.A474P | Missense Mutation (SNP) | VAF 110/515 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58815713; called by muse, mutect2, varscan2
- KSR2 | c.1486C>A p.Q496K | Missense Mutation (SNP) | VAF 109/404 reads (27%) | SIFT tolerated (0.93); PolyPhen benign (0.011); catalogued as COSV56675851; called by muse, mutect2, varscan2
- LATS2 | c.2320G>C p.E774Q | Missense Mutation (SNP) | VAF 33/244 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV104430060; called by muse, mutect2, varscan2
- LGSN | c.288C>A p.H96Q | Missense Mutation (SNP) | VAF 40/243 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs146253789; called by muse, mutect2, varscan2
- LONRF3 | c.568C>T p.R190W | Missense Mutation (SNP) | VAF 60/259 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs948909684; called by muse, mutect2, varscan2
- LOXHD1 | c.902C>A p.T301N | Missense Mutation (SNP) | VAF 71/253 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.083); catalogued as rs1222285017, COSV59661097; called by muse, mutect2, varscan2
- LRP1B | c.9300C>A p.N3100K | Missense Mutation (SNP) | VAF 49/140 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99081287; called by muse, mutect2, varscan2
- MAP2K7 | c.1105C>T p.P369S | Missense Mutation (SNP) | VAF 26/152 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1330906396; called by muse, mutect2, varscan2
- MFN2 | c.478G>A p.V160M | Missense Mutation (SNP) | VAF 142/586 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs1301112706; called by muse, mutect2, varscan2
- MLX | c.314C>T p.S105F | Missense Mutation (SNP) | VAF 60/323 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as rs756258939; called by muse, mutect2, varscan2
- MLXIPL | c.1655G>A p.R552Q | Missense Mutation (SNP) | VAF 116/373 reads (31%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.638); catalogued as rs369473784; called by muse, mutect2, varscan2
- MPPED2 | c.490G>C p.D164H | Missense Mutation (SNP) | VAF 51/211 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63899353; called by muse, mutect2, varscan2
- NAALAD2 | c.1796C>A p.A599E | Missense Mutation (SNP) | VAF 51/194 reads (26%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV100428580; called by muse, mutect2, varscan2
- NCOR1 | c.4798C>T p.Q1600* | Nonsense Mutation (SNP) | VAF 20/318 reads (6%) | catalogued as COSV51987660; called by muse, mutect2
- NOS2 | c.2515del p.T839Pfs*45 | Frame Shift Del (DEL) | VAF 46/244 reads (19%) | catalogued as rs780039206, COSV58223688; called by mutect2, pindel, varscan2
- OR14A2 | c.827A>T p.Y276F | Missense Mutation (SNP) | VAF 73/299 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs959716611; called by muse, mutect2, varscan2
- OR14J1 | c.145G>C p.V49L | Missense Mutation (SNP) | VAF 166/454 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65845719; called by muse, mutect2, varscan2
- OR2G2 | c.368G>C p.C123S | Missense Mutation (SNP) | VAF 66/212 reads (31%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV60741054; called by muse, mutect2, varscan2
- OR2G3 | c.802C>T p.Q268* | Nonsense Mutation (SNP) | VAF 47/257 reads (18%) | catalogued as COSV60682928; called by muse, mutect2, varscan2
- OR2M5 | c.758G>T p.G253V | Missense Mutation (SNP) | VAF 106/428 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100822785, COSV100822882, COSV63546894; called by muse, mutect2, varscan2
- OR2T27 | c.413G>T p.R138L | Missense Mutation (SNP) | VAF 77/608 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.023); catalogued as rs757391223, COSV100788324, COSV61281501, COSV61283032; called by muse, mutect2, varscan2
- OR2T3 | c.362C>A p.A121D | Missense Mutation (SNP) | VAF 88/322 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV62083094; called by muse, varscan2
- OR52M1 | c.492G>T p.M164I | Missense Mutation (SNP) | VAF 29/113 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as COSV64172766, COSV64172836; called by muse, mutect2, varscan2
- OR52N5 | c.358G>T p.E120* | Nonsense Mutation (SNP) | VAF 67/149 reads (45%) | catalogued as rs1341893088, COSV57698878, COSV57699126; called by muse, mutect2, varscan2
- OR5D13 | c.273C>A p.Y91* | Nonsense Mutation (SNP) | VAF 66/265 reads (25%) | catalogued as COSV62333996; called by muse, mutect2, varscan2
- OR6Q1 | c.793C>A p.Q265K | Missense Mutation (SNP) | VAF 86/360 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV100109944; called by muse, varscan2
- PAG1 | c.421G>A p.A141T | Missense Mutation (SNP) | VAF 26/408 reads (6%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs775054099, COSV55058178; called by muse, mutect2
- PCDHA8 | c.2115C>A p.C705* | Nonsense Mutation (SNP) | VAF 67/656 reads (10%) | catalogued as rs781786542, COSV65333833; called by muse, mutect2, varscan2
- PCDHB7 | c.1777G>T p.D593Y | Missense Mutation (SNP) | VAF 198/1054 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99176467; called by mutect2, varscan2
- PCSK6 | c.1691C>T p.S564L | Missense Mutation (SNP) | VAF 28/121 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.192); catalogued as rs777354632; called by muse, mutect2, varscan2
- PDPR | c.2219G>T p.R740L | Missense Mutation (SNP) | VAF 21/174 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.072); catalogued as COSV55356134; called by muse, mutect2
- PIGN | c.2529G>T p.M843I | Missense Mutation (SNP) | VAF 29/124 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.046); catalogued as rs868445630; called by muse, mutect2, varscan2
- PPP1R9A | c.1573G>T p.A525S | Missense Mutation (SNP) | VAF 49/209 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as COSV56911578; called by muse, mutect2, varscan2
- PRODH2 | c.862C>T p.Q288* (on ENST00000301175; = p.Q212* on NM_021232.2 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 79/324 reads (24%) | catalogued as COSV56561992; called by muse, varscan2
- PRRC2B | c.5860G>A p.A1954T | Missense Mutation (SNP) | VAF 95/372 reads (26%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as rs756979652, COSV100261166; called by muse, mutect2, varscan2
- PRSS35 | c.107G>T p.R36L | Missense Mutation (SNP) | VAF 152/478 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV63800436, COSV63801045; called by muse, mutect2, varscan2
- R3HCC1L | c.1435G>A p.A479T | Missense Mutation (SNP) | VAF 37/143 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.121); catalogued as rs756856068; called by muse, mutect2, varscan2
- RAB6B | c.268G>T p.V90L | Missense Mutation (SNP) | VAF 86/303 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.685); catalogued as COSV53312195; called by muse, mutect2, varscan2
- RELN | c.1513G>T p.E505* | Nonsense Mutation (SNP) | VAF 64/273 reads (23%) | catalogued as COSV100635150, COSV59034599; called by muse, mutect2, varscan2
- RIT2 | c.83C>A p.A28E | Missense Mutation (SNP) | VAF 92/273 reads (34%) | SIFT tolerated (0.27); PolyPhen benign (0.043); catalogued as COSV56310350; called by muse, mutect2, varscan2
- ROBO2 | c.586A>T p.S196C | Missense Mutation (SNP) | VAF 61/274 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs777582973; called by muse, mutect2, varscan2
- RTP2 | c.418C>A p.H140N | Missense Mutation (SNP) | VAF 132/351 reads (38%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.761); catalogued as COSV64078935; called by muse, mutect2, varscan2
- RYR3 | c.9750C>G p.I3250M (on ENST00000389232; = p.I3251M on NM_001036.6) | Missense Mutation (SNP) | VAF 120/450 reads (27%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.942); catalogued as rs777542819, COSV66776218; called by muse, mutect2, varscan2
- SAA1 | c.239G>A p.R80K | Missense Mutation (SNP) | VAF 12/190 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.927); catalogued as COSV62946155, COSV62946538; called by muse, mutect2
- SCRIB | c.3017G>A p.R1006H | Missense Mutation (SNP) | VAF 34/169 reads (20%) | SIFT tolerated (0.57); PolyPhen benign (0.005); catalogued as rs782313329; called by muse, mutect2, varscan2
- SLAMF1 | c.481A>C p.I161L | Missense Mutation (SNP) | VAF 83/291 reads (29%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV52500100; called by muse, mutect2, varscan2
- SLC13A1 | c.743C>T p.S248F | Missense Mutation (SNP) | VAF 91/385 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs766787346, COSV52013916; called by muse, mutect2, varscan2
- SLC16A14 | c.271G>T p.G91C | Missense Mutation (SNP) | VAF 57/142 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV54617699; called by muse, mutect2, varscan2
- SLC39A10 | c.754C>T p.P252S | Missense Mutation (SNP) | VAF 56/168 reads (33%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs1156860399, COSV100660495; called by muse, mutect2, varscan2
- SLC7A2 | c.50G>A p.R17K (on ENST00000494857 / NM_001370338.1; = p.R57K on NM_003046.6) | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.033); catalogued as COSV50249581; called by muse, mutect2, varscan2
- SLIT1 | c.1391C>T p.A464V | Missense Mutation (SNP) | VAF 79/478 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV56582913; called by muse, mutect2, varscan2
- SLIT2 | c.613C>A p.R205= | Splice Region (SNP) | VAF 14/79 reads (18%) | catalogued as COSV56583398; called by muse, mutect2, varscan2
- SLIT2 | c.1615C>A p.R539S | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); catalogued as COSV56584121; called by muse, mutect2, varscan2
- SMARCA4 | c.3813C>A p.F1271L | Missense Mutation (SNP) | VAF 50/782 reads (6%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV60799676; called by muse, mutect2
- SMARCE1 | c.1123G>A p.D375N | Missense Mutation (SNP) | VAF 154/552 reads (28%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.041); catalogued as rs746301638; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SPATA48 | c.905C>A p.S302Y | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.667); catalogued as rs1237268798; called by muse, mutect2, varscan2
- SPOCK3 | c.357C>A p.H119Q | Missense Mutation (SNP) | VAF 4/73 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.811); catalogued as rs1172220212; called by muse, mutect2
- SREBF2 | c.3328G>T p.A1110S | Missense Mutation (SNP) | VAF 141/586 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); catalogued as rs1420863565; called by muse, mutect2, varscan2
- SUSD3 | c.425G>T p.R142M | Missense Mutation (SNP) | VAF 69/200 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV64937322; called by muse, mutect2, varscan2
- SYCN | c.250C>T p.P84S | Missense Mutation (SNP) | VAF 32/487 reads (7%) | SIFT tolerated (0.42); PolyPhen benign (0.04); catalogued as COSV59212522; called by muse, mutect2
- TAF11 | c.484G>T p.V162F | Missense Mutation (SNP) | VAF 30/398 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs377382395; called by muse, mutect2
- TBC1D9B | c.1937C>T p.T646M | Missense Mutation (SNP) | VAF 33/234 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.837); catalogued as rs911263386, COSV62281615; called by muse, mutect2
- TGFBR1 | c.494C>A p.S165* | Nonsense Mutation (SNP) | VAF 32/392 reads (8%) | catalogued as COSV66626116; called by muse, mutect2
- TIAM1 | c.525C>G p.I175M | Missense Mutation (SNP) | VAF 65/289 reads (22%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.007); catalogued as rs771021898, COSV54556457; called by muse, mutect2, varscan2
- TLCD1 | c.194+3G>C | Splice Region (SNP) | VAF 24/425 reads (6%) | catalogued as rs1178500094; called by muse, mutect2
- TNR | c.1963+1G>T p.X655_splice | Splice Site (SNP) | VAF 20/86 reads (23%) | catalogued as COSV54898935; called by muse, varscan2
- TP53 | c.216_217insT p.V73Cfs*76 | Frame Shift Ins (INS) | VAF 115/340 reads (34%) | catalogued as COSV104369723; called by mutect2, pindel, varscan2
- TPR | c.5779C>T p.Q1927* | Nonsense Mutation (SNP) | VAF 18/471 reads (4%) | catalogued as rs867210122; called by muse, mutect2
- TRANK1 | c.3301A>G p.I1101V | Missense Mutation (SNP) | VAF 77/357 reads (22%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs1253113309; called by muse, mutect2, varscan2
- TRIM64C | c.85G>T p.D29Y | Missense Mutation (SNP) | VAF 90/419 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as rs1245008865; called by muse, mutect2, varscan2
- TRIM67 | c.2326G>T p.G776W | Missense Mutation (SNP) | VAF 34/209 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.782); catalogued as COSV64160647; called by muse, mutect2, varscan2
- UMOD | c.1216C>A p.L406I | Missense Mutation (SNP) | VAF 105/345 reads (30%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.963); catalogued as COSV56773113; called by muse, mutect2, varscan2
- VHL | c.98C>G p.S33W | Missense Mutation (SNP) | VAF 10/198 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.367); catalogued as COSV56561052; called by muse, mutect2
- VSIG10L | c.1718C>A p.T573K | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.433); catalogued as COSV59470888; called by muse, mutect2, varscan2
- XKR4 | c.571G>T p.D191Y | Missense Mutation (SNP) | VAF 52/207 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.608); catalogued as COSV100531505; called by muse, mutect2, varscan2
- YIPF7 | c.46G>T p.D16Y | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.176); catalogued as rs1036713066; called by muse, mutect2, varscan2
- ZFHX4 | c.9440C>T p.A3147V | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as rs754838273, COSV50479252; called by muse, mutect2, varscan2
- ZNF154 | c.221C>G p.A74G | Missense Mutation (SNP) | VAF 45/147 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.109); catalogued as rs767078067; called by muse, mutect2, varscan2
- ZNF264 | c.1801G>T p.A601S | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV54041441; called by muse, mutect2, varscan2
- ZNF462 | c.4588G>T p.V1530L | Missense Mutation (SNP) | VAF 84/217 reads (39%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.997); catalogued as COSV52938225; called by muse, mutect2, varscan2
- ZNF665 | c.960G>A p.M320I (on ENST00000600412; = p.M385I on NM_024733.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/118 reads (31%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs757725691; called by muse, mutect2, varscan2
- ZNF676 | c.75G>C p.Q25H | Missense Mutation (SNP) | VAF 58/308 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV101236166; called by muse, varscan2
- ZNF835 | c.10C>T p.L4F | Missense Mutation (SNP) | VAF 122/583 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.447); catalogued as rs1264888746, COSV101606382; called by muse, mutect2, varscan2
- AADAC | c.557C>T p.S186F | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- ABCC11 | c.802G>T p.V268L | Missense Mutation (SNP) | VAF 18/190 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.045); called by muse, mutect2
- ABHD13 | c.68G>T p.W23L | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ACAA1 | c.888G>C p.L296F | Missense Mutation (SNP) | VAF 56/250 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- ACAD11 | c.2338A>G p.I780V | Missense Mutation (SNP) | VAF 21/111 reads (19%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- ACAN | c.7150C>T p.R2384C (on ENST00000560601 / NM_001369268.1; = p.R2308C on NM_001135.3) | Missense Mutation (SNP) | VAF 13/418 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.945); called by muse, mutect2
- ADGRB2 | c.1452G>T p.W484C | Missense Mutation (SNP) | VAF 37/163 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADGRL3 | c.4636C>A p.Q1546K (on ENST00000506720 / NM_001322402.2; = p.Q1435K on NM_015236.6) | Missense Mutation (SNP) | VAF 75/325 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.489); called by muse, mutect2, varscan2
- ALK | c.1740G>T p.M580I | Missense Mutation (SNP) | VAF 113/438 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ANKRD30B | c.1339A>G p.K447E | Missense Mutation (SNP) | VAF 35/161 reads (22%) | SIFT tolerated (0.8); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- APOF | c.19T>A p.Y7N | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ARF5 | c.323A>T p.Q108L | Missense Mutation (SNP) | VAF 71/287 reads (25%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- ARMC5 | c.227G>T p.R76L | Missense Mutation (SNP) | VAF 97/538 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.7); called by muse, mutect2, varscan2
- ASPRV1 | c.288_289insG p.R97Afs*11 | Frame Shift Ins (INS) | VAF 63/305 reads (21%) | called by mutect2, pindel, varscan2
- ASRGL1 | c.758G>T p.G253V | Missense Mutation (SNP) | VAF 116/503 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- ATAD2B | c.449A>T p.K150M | Missense Mutation (SNP) | VAF 43/154 reads (28%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- ATG16L2 | c.710+5G>C | Splice Region (SNP) | VAF 28/450 reads (6%) | called by muse, mutect2
- ATP2B4 | c.2443G>A p.D815N | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2
- AVEN | c.187C>T p.R63C | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.266); called by muse, mutect2, varscan2
- BNIP5 | c.76G>T p.G26W | Missense Mutation (SNP) | VAF 54/287 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- BORCS6 | c.902G>T p.R301L | Missense Mutation (SNP) | VAF 142/411 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CADM1 | c.1126G>C p.V376L | Missense Mutation (SNP) | VAF 146/605 reads (24%) | SIFT tolerated (0.54); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- CALB2 | c.113G>T p.G38V | Missense Mutation (SNP) | VAF 16/212 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CCDC105 | c.829G>T p.G277C | Missense Mutation (SNP) | VAF 71/351 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- CCDC168 | c.19915A>T p.N6639Y | Missense Mutation (SNP) | VAF 36/141 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- CCDC85A | c.1355G>A p.S452N | Missense Mutation (SNP) | VAF 14/174 reads (8%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.173); called by muse, mutect2
- CDHR3 | c.2323A>T p.T775S | Missense Mutation (SNP) | VAF 46/194 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- CDHR5 | c.527C>T p.S176F | Missense Mutation (SNP) | VAF 11/313 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); called by muse, mutect2
- CDK2AP2 | c.132C>G p.F44L | Missense Mutation (SNP) | VAF 34/262 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- CEBPA | c.910A>G p.K304E | Missense Mutation (SNP) | VAF 257/1010 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CELF5 | c.719C>T p.P240L | Missense Mutation (SNP) | VAF 70/293 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- CEMIP2 | c.3597G>T p.Q1199H | Missense Mutation (SNP) | VAF 42/102 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.864); called by muse, mutect2
- CES5A | c.601G>T p.A201S | Missense Mutation (SNP) | VAF 22/282 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- CHI3L1 | c.310C>G p.Q104E | Missense Mutation (SNP) | VAF 34/131 reads (26%) | SIFT tolerated (0.38); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CNBD1 | c.226C>A p.H76N | Missense Mutation (SNP) | VAF 16/141 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- CNKSR2 | c.1506G>T p.K502N | Missense Mutation (SNP) | VAF 77/156 reads (49%) | SIFT tolerated (0.42); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CNMD | c.453C>A p.S151R | Missense Mutation (SNP) | VAF 43/120 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- CNTN4 | c.2251G>T p.V751L | Missense Mutation (SNP) | VAF 83/409 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.718); called by muse, mutect2, varscan2
- COL12A1 | c.5252-2A>T p.X1751_splice | Splice Site (SNP) | VAF 179/504 reads (36%) | called by muse, mutect2, varscan2
- COL4A4 | c.799C>T p.L267F | Missense Mutation (SNP) | VAF 86/342 reads (25%) | SIFT tolerated (0.73); PolyPhen possibly damaging (0.546); called by muse, mutect2, varscan2
- CPA3 | c.17del p.P6Lfs*4 | Frame Shift Del (DEL) | VAF 25/190 reads (13%) | called by mutect2, pindel, varscan2
- CPB1 | c.1183C>G p.R395G | Missense Mutation (SNP) | VAF 98/366 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.278); called by muse, mutect2, varscan2
- CPNE4 | c.671G>C p.R224P | Missense Mutation (SNP) | VAF 92/324 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- CSMD3 | c.9689-1G>A p.X3230_splice (on ENST00000297405 / NM_001363185.1; = p.X3061_splice on NM_052900.3) | Splice Site (SNP) | VAF 69/318 reads (22%) | called by muse, mutect2, varscan2
- CTNNB1 | c.1924G>A p.E642K | Missense Mutation (SNP) | VAF 110/446 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.404); called by muse, mutect2, varscan2
- CTR9 | c.931C>T p.Q311* | Nonsense Mutation (SNP) | VAF 12/158 reads (8%) | called by muse, mutect2
- DAXX | c.118A>T p.S40C | Missense Mutation (SNP) | VAF 180/450 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.34); called by muse, mutect2, varscan2
- DCSTAMP | c.1142G>C p.S381T | Missense Mutation (SNP) | VAF 72/314 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.181); called by muse, mutect2, varscan2
- DCTN2 | c.392A>G p.E131G (on ENST00000548249 / NM_001261413.2; = p.E136G on NM_006400.4) | Missense Mutation (SNP) | VAF 54/187 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- DDI2 | c.33_41del p.D11_S13del | In Frame Del (DEL) | VAF 46/236 reads (19%) | called by mutect2, pindel, varscan2
- DDX24 | c.628C>G p.L210V | Missense Mutation (SNP) | VAF 28/300 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); called by muse, mutect2
- DDX24 | c.202C>G p.L68V | Missense Mutation (SNP) | VAF 25/220 reads (11%) | SIFT tolerated (0.54); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- DEFB114 | c.144C>A p.D48E | Missense Mutation (SNP) | VAF 23/215 reads (11%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.374); called by muse, mutect2, varscan2
- DLG2 | c.1267G>T p.V423F | Missense Mutation (SNP) | VAF 44/167 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- DLX5 | c.312C>A p.Y104* | Nonsense Mutation (SNP) | VAF 34/146 reads (23%) | called by muse, mutect2, varscan2
- DNAH11 | c.3698G>C p.R1233T | Missense Mutation (SNP) | VAF 48/264 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.71); called by muse, mutect2, varscan2
- DNAH5 | c.9723C>A p.V3241= | Splice Region (SNP) | VAF 29/244 reads (12%) | called by muse, mutect2, varscan2
- DOCK2 | c.2898G>T p.V966= | Splice Region (SNP) | VAF 17/164 reads (10%) | called by muse, mutect2, varscan2
- DOCK2 | c.2898+1G>T p.X966_splice | Splice Site (SNP) | VAF 16/159 reads (10%) | called by muse, mutect2, varscan2
- DPP10 | c.366+1del p.X122_splice | Splice Site (DEL) | VAF 15/68 reads (22%) | called by mutect2, pindel, varscan2
- DYNC1I1 | c.74A>G p.K25R | Missense Mutation (SNP) | VAF 40/185 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- EDEM1 | c.1509+1del | Frame Shift Del (DEL) | VAF 71/390 reads (18%) | called by mutect2, pindel, varscan2
- EEPD1 | c.924G>T p.L308F | Missense Mutation (SNP) | VAF 64/312 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- EFHC1 | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 30/676 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.075); called by muse, mutect2
- EHD1 | c.949G>C p.E317Q | Missense Mutation (SNP) | VAF 80/329 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- EML6 | c.3778G>C p.D1260H | Missense Mutation (SNP) | VAF 41/149 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ERC1 | c.1448T>C p.L483P (on ENST00000360905 / NM_178040.4; = p.L455P on NM_178039.4) | Missense Mutation (SNP) | VAF 68/243 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ETFDH | c.1104A>T p.E368D | Missense Mutation (SNP) | VAF 91/402 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ETV3 | c.721C>T p.P241S | Missense Mutation (SNP) | VAF 74/329 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.226); called by muse, mutect2, varscan2
- EVA1C | c.495C>G p.N165K | Missense Mutation (SNP) | VAF 37/141 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- F5 | c.1832A>T p.H611L | Missense Mutation (SNP) | VAF 101/411 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- FAM172A | c.42G>T p.W14C | Missense Mutation (SNP) | VAF 61/200 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM71E2 | c.2764dup p.A922Gfs*26 | Frame Shift Ins (INS) | VAF 82/366 reads (22%) | called by mutect2, pindel, varscan2
- FAM78B | c.67G>T p.V23L | Missense Mutation (SNP) | VAF 34/125 reads (27%) | SIFT tolerated (0.98); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAT4 | c.12578G>C p.G4193A | Missense Mutation (SNP) | VAF 34/139 reads (24%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FBXL20 | c.88A>G p.K30E | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- FCGBP | c.7739C>T p.P2580L | Missense Mutation (SNP) | VAF 108/881 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- FCSK | c.1834G>A p.D612N | Missense Mutation (SNP) | VAF 67/235 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- FLNA | c.1309C>G p.R437G | Missense Mutation (SNP) | VAF 14/304 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.022); called by muse, mutect2
- FOSL1 | c.470A>T p.Q157L | Missense Mutation (SNP) | VAF 43/149 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- FOXO3 | c.1018G>A p.D340N | Missense Mutation (SNP) | VAF 11/176 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.286); called by muse, mutect2
- FOXO3 | c.1634G>C p.G545A | Missense Mutation (SNP) | VAF 46/842 reads (5%) | SIFT tolerated (0.89); PolyPhen benign (0.138); called by muse, mutect2
- FRMD1 | c.110G>T p.C37F | Missense Mutation (SNP) | VAF 24/169 reads (14%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- FSIP2 | c.9662C>A p.S3221* | Nonsense Mutation (SNP) | VAF 20/69 reads (29%) | called by muse, mutect2, varscan2
- GALNT13 | c.1276C>A p.R426S | Missense Mutation (SNP) | VAF 38/105 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- GBA3 | c.1082A>T p.K361M | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.456); called by muse, varscan2
- GC | c.814G>A p.D272N | Missense Mutation (SNP) | VAF 9/109 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.809); called by muse, mutect2
- GFRAL | c.22G>T p.A8S | Missense Mutation (SNP) | VAF 30/200 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- GOLGA6L2 | c.246A>G p.E82= | Splice Region (SNP) | VAF 116/439 reads (26%) | called by muse, mutect2, varscan2
- GOLGA6L22 | c.335G>T p.R112M | Missense Mutation (SNP) | VAF 94/631 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- GPR149 | c.1610G>C p.R537T | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GPR6 | c.771C>A p.H257Q | Missense Mutation (SNP) | VAF 173/436 reads (40%) | SIFT tolerated (0.47); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- GZMA | c.566C>A p.P189H | Missense Mutation (SNP) | VAF 70/208 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- HDAC9 | c.778G>A p.E260K | Missense Mutation (SNP) | VAF 83/234 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.772); called by muse, mutect2, varscan2
- HECTD1 | c.7104C>G p.I2368M | Missense Mutation (SNP) | VAF 42/359 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HEPH | c.83G>T p.R28I | Missense Mutation (SNP) | VAF 66/120 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- HFM1 | c.1601G>A p.C534Y | Missense Mutation (SNP) | VAF 24/131 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HGD | c.188G>T p.R63M | Missense Mutation (SNP) | VAF 105/418 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HHLA2 | c.28T>C p.F10L | Missense Mutation (SNP) | VAF 42/194 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- HMCN2 | c.11822C>G p.S3941C | Missense Mutation (SNP) | VAF 50/142 reads (35%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- HS6ST3 | c.235C>T p.P79S | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IGF2R | c.7289A>T p.E2430V | Missense Mutation (SNP) | VAF 114/259 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- IGFN1 | c.2618G>T p.G873V (on ENST00000295591 / NM_001367841.1; = p.G3330V on NM_001164586.2) | Missense Mutation (SNP) | VAF 66/367 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- IGHG2 | c.889C>A p.Q297K | Missense Mutation (SNP) | VAF 121/676 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0.028); called by muse, varscan2
- IGHV1OR21-1 | c.101G>T p.G34V | Missense Mutation (SNP) | VAF 94/1128 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- IGHV3OR16-9 | c.280T>A p.Y94N | Missense Mutation (SNP) | VAF 31/189 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- IGKV1D-16 | c.268G>T p.G90W | Missense Mutation (SNP) | VAF 178/626 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.728); called by mutect2, varscan2
- IGSF1 | c.3424C>A p.P1142T | Missense Mutation (SNP) | VAF 65/127 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- IL23R | c.900del p.R302Gfs*35 | Frame Shift Del (DEL) | VAF 70/377 reads (19%) | called by mutect2, pindel, varscan2
- IL26 | c.254T>A p.L85H | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- IQCE | c.115C>T p.P39S | Missense Mutation (SNP) | VAF 28/241 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- ITPKB | c.1468G>T p.E490* | Nonsense Mutation (SNP) | VAF 80/339 reads (24%) | called by muse, mutect2, varscan2
- KATNBL1 | c.291G>T p.M97I | Missense Mutation (SNP) | VAF 118/469 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- KIAA1549L | c.2050C>G p.L684V (on ENST00000321505; = p.L981V on NM_012194.3) | Missense Mutation (SNP) | VAF 90/324 reads (28%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- KLF11 | c.171G>T p.W57C | Missense Mutation (SNP) | VAF 137/515 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KLHL21 | c.835C>A p.R279S | Missense Mutation (SNP) | VAF 11/272 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2
- KLHL7 | c.235G>C p.E79Q (on ENST00000339077 / NM_001031710.3; = p.E31Q on NM_018846.5) | Missense Mutation (SNP) | VAF 79/390 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KLRA1P | n.211+1G>T | Splice Site (SNP) | VAF 69/314 reads (22%) | called by muse, mutect2, varscan2
- LAMP5 | c.773T>A p.V258D | Missense Mutation (SNP) | VAF 50/281 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.354); called by muse, mutect2, varscan2
- LGI4 | c.886del p.R296Gfs*174 | Frame Shift Del (DEL) | VAF 83/304 reads (27%) | called by mutect2, pindel, varscan2
- LRRC37B | c.1535A>T p.Q512L | Missense Mutation (SNP) | VAF 137/518 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- LRRC42 | c.1189G>C p.E397Q | Missense Mutation (SNP) | VAF 56/390 reads (14%) | SIFT tolerated (0.44); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- LRRFIP1 | c.1784T>G p.L595* (on ENST00000392000 / NM_001137552.2; = p.L571* on NM_004735.4) | Nonsense Mutation (SNP) | VAF 59/159 reads (37%) | called by muse, mutect2, varscan2
- LY75 | c.254G>T p.G85V | Missense Mutation (SNP) | VAF 20/272 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MARCKS | c.991del p.A331Qfs*38 | Frame Shift Del (DEL) | VAF 82/264 reads (31%) | called by mutect2, pindel, varscan2
- MET | c.4040A>C p.E1347A | Missense Mutation (SNP) | VAF 109/476 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- MIER2 | c.995G>T p.R332L | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- MS4A6A | c.630G>T p.Q210H | Missense Mutation (SNP) | VAF 101/473 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- MSLNL | c.1006C>T p.L336F | Missense Mutation (SNP) | VAF 12/282 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2
- MSMP | c.130+2T>A p.X44_splice | Splice Site (SNP) | VAF 47/84 reads (56%) | called by muse, mutect2, varscan2
- MTMR11 | c.1796C>G p.S599C (on ENST00000439741 / NM_001145862.2; = p.S527C on NM_181873.3) | Missense Mutation (SNP) | VAF 101/588 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.739); called by muse, mutect2, varscan2
- MTMR3 | c.250A>T p.I84L | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- MUC12 | c.1710C>A p.S570R (on ENST00000379442; = p.S427R on NM_001164462.1) | Missense Mutation (SNP) | VAF 77/645 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.316); called by muse, mutect2, varscan2
- MUC16 | c.23299C>T p.H7767Y | Missense Mutation (SNP) | VAF 53/239 reads (22%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- MUC16 | c.7897G>C p.G2633R | Missense Mutation (SNP) | VAF 91/367 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- MUC19 | c.492C>A p.A164= | Splice Region (SNP) | VAF 20/68 reads (29%) | called by muse, varscan2
- MUTYH | c.339G>T p.R113= | Splice Region (SNP) | VAF 164/672 reads (24%) | called by muse, mutect2, varscan2
- MYOM1 | c.351G>T p.K117N | Missense Mutation (SNP) | VAF 41/269 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.793); called by muse, mutect2, varscan2
- MYOM3 | c.4084C>A p.P1362T | Missense Mutation (SNP) | VAF 67/249 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NBAS | c.6913T>G p.S2305A | Missense Mutation (SNP) | VAF 82/273 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- NDOR1 | c.929G>C p.R310P | Missense Mutation (SNP) | VAF 114/340 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- NEK10 | c.967G>C p.E323Q | Missense Mutation (SNP) | VAF 16/440 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.92); called by muse, mutect2
- NEUROD1 | c.956C>T p.S319L | Missense Mutation (SNP) | VAF 10/256 reads (4%) | SIFT tolerated (0.64); PolyPhen benign (0.026); called by muse, mutect2
- NEUROD1 | c.855C>G p.F285L | Missense Mutation (SNP) | VAF 32/774 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2
- NIPSNAP2 | c.788A>T p.Y263F | Missense Mutation (SNP) | VAF 53/202 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- NR4A3 | c.1466C>A p.A489D | Missense Mutation (SNP) | VAF 47/120 reads (39%) | SIFT tolerated (0.48); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- NTNG1 | c.410C>A p.S137Y | Missense Mutation (SNP) | VAF 113/300 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- NUP58 | c.1046T>C p.L349S | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.56); called by muse, mutect2, varscan2
- OOSP1 | c.71G>T p.W24L | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.401); called by muse, mutect2, varscan2
- OR10R2 | c.703T>A p.C235S | Missense Mutation (SNP) | VAF 61/221 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- OR1M1 | c.490G>T p.A164S | Missense Mutation (SNP) | VAF 106/460 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- OR2J2 | c.372dup p.V125Cfs*5 | Frame Shift Ins (INS) | VAF 20/152 reads (13%) | called by mutect2, varscan2
- OR2J2 | c.373delinsTT p.V125Ffs*5 | Frame Shift Ins (INS) | VAF 18/141 reads (13%) | called by mutect2*, pindel, varscan2*
- OR2T3 | c.304T>A p.C102S | Missense Mutation (SNP) | VAF 124/481 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- OR4C13 | c.341C>T p.T114I | Missense Mutation (SNP) | VAF 43/166 reads (26%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- OR4K14 | c.179T>C p.M60T | Missense Mutation (SNP) | VAF 44/230 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); called by muse, mutect2, varscan2
- OR4M1 | c.672G>T p.L224F | Missense Mutation (SNP) | VAF 82/561 reads (15%) | SIFT tolerated (0.59); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- OR52B4 | c.334T>A p.S112T | Missense Mutation (SNP) | VAF 79/338 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR52N1 | c.857T>C p.M286T | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.181); called by muse, mutect2, varscan2
- OR5AK2 | c.823T>A p.F275I | Missense Mutation (SNP) | VAF 34/176 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OR6S1 | c.543C>G p.F181L | Missense Mutation (SNP) | VAF 41/185 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- OR8B2 | c.415C>T p.Q139* | Nonsense Mutation (SNP) | VAF 16/445 reads (4%) | called by muse, mutect2
- OTOF | c.4363G>T p.G1455C (on ENST00000272371 / NM_194248.3; = p.G688C on NM_004802.4) | Missense Mutation (SNP) | VAF 148/537 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OTUD7A | c.2720G>T p.R907L (on ENST00000307050 / NM_001382637.1; = p.R900L on NM_130901.3) | Missense Mutation (SNP) | VAF 56/188 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PAPPA | c.4777-2A>G p.X1593_splice | Splice Site (SNP) | VAF 34/156 reads (22%) | called by muse, mutect2
- PATL2 | c.241C>T p.P81S | Missense Mutation (SNP) | VAF 38/172 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PCDHA10 | c.1537A>T p.S513C | Missense Mutation (SNP) | VAF 295/1051 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PCDHA7 | c.229G>T p.V77L | Missense Mutation (SNP) | VAF 93/610 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.397); called by muse, mutect2, varscan2
- PCDHGA6 | c.74G>T p.G25V | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); called by muse, mutect2
- PCDHGA7 | c.1795G>T p.G599C | Missense Mutation (SNP) | VAF 46/366 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHGA7 | c.1796G>T p.G599V | Missense Mutation (SNP) | VAF 45/364 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHGB6 | c.1700T>A p.L567Q | Missense Mutation (SNP) | VAF 128/429 reads (30%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PKHD1 | c.8287G>C p.V2763L | Missense Mutation (SNP) | VAF 158/465 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); called by muse, mutect2, varscan2
- PLXNA1 | c.2728G>T p.V910L | Missense Mutation (SNP) | VAF 105/427 reads (25%) | SIFT tolerated (0.76); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- POLK | c.1283C>A p.A428E | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- PPFIA2 | c.2002C>T p.Q668* | Nonsense Mutation (SNP) | VAF 64/272 reads (24%) | called by muse, mutect2, varscan2
- PPM1J | c.665C>T p.S222L | Missense Mutation (SNP) | VAF 13/125 reads (10%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2, varscan2
- PPP2R5E | c.362G>T p.C121F | Missense Mutation (SNP) | VAF 57/203 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- PRELID3B | c.19G>T p.E7* | Nonsense Mutation (SNP) | VAF 96/407 reads (24%) | called by muse, mutect2, varscan2
- PROM2 | c.599T>C p.L200P | Missense Mutation (SNP) | VAF 63/266 reads (24%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- PRRC2A | c.946G>C p.D316H | Missense Mutation (SNP) | VAF 14/287 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PRTG | c.1711G>T p.G571W | Missense Mutation (SNP) | VAF 158/613 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PTDSS1 | c.1148A>G p.Y383C | Missense Mutation (SNP) | VAF 33/197 reads (17%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.598); called by muse, mutect2, varscan2
- PTPDC1 | c.1761G>T p.E587D (on ENST00000375360 / NM_177995.3; = p.E639D on NM_152422.4) | Missense Mutation (SNP) | VAF 82/218 reads (38%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.467); called by muse, mutect2, varscan2
- RAB3IP | c.395G>C p.R132T (on ENST00000550536 / NM_175623.4; = p.R116T on NM_022456.5) | Missense Mutation (SNP) | VAF 68/439 reads (15%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- RABL2B | c.117G>C p.E39D | Missense Mutation (SNP) | VAF 23/416 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- RANBP17 | c.1387T>G p.L463V | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- RBM6 | c.1072C>T p.Q358* | Nonsense Mutation (SNP) | VAF 37/180 reads (21%) | called by muse, mutect2, varscan2
- RLF | c.1019G>C p.C340S | Missense Mutation (SNP) | VAF 57/235 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.517); called by muse, mutect2, varscan2
- RP1 | c.4126A>T p.T1376S | Missense Mutation (SNP) | VAF 27/185 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SAMHD1 | c.451G>T p.G151* | Nonsense Mutation (SNP) | VAF 123/512 reads (24%) | called by muse, mutect2, varscan2
- SCN3A | c.1781C>G p.A594G | Missense Mutation (SNP) | VAF 25/389 reads (6%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.954); called by muse, mutect2
- SETD2 | c.5710G>C p.D1904H | Missense Mutation (SNP) | VAF 90/352 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- SI | c.578A>T p.K193M | Missense Mutation (SNP) | VAF 73/306 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- SKOR2 | c.1094G>T p.G365V | Missense Mutation (SNP) | VAF 36/130 reads (28%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- SLC13A2 | c.801C>A p.F267L | Missense Mutation (SNP) | VAF 63/213 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.496); called by muse, mutect2, varscan2
- SLC22A15 | c.388G>T p.G130C | Missense Mutation (SNP) | VAF 60/189 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC24A4 | c.236A>C p.D79A | Missense Mutation (SNP) | VAF 10/194 reads (5%) | SIFT tolerated (0.57); PolyPhen benign (0.001); called by muse, mutect2
- SLC39A12 | c.545G>T p.C182F | Missense Mutation (SNP) | VAF 50/179 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SLC8A1 | c.1179G>T p.M393I | Missense Mutation (SNP) | VAF 30/123 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SMCO3 | c.178G>C p.G60R | Missense Mutation (SNP) | VAF 63/271 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- SPARC | c.607G>A p.E203K | Missense Mutation (SNP) | VAF 34/217 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- SPATA6 | c.836G>T p.C279F | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- SPEF2 | c.2668G>C p.E890Q | Missense Mutation (SNP) | VAF 6/101 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.04); called by muse, mutect2
- SPPL3 | c.1097G>T p.R366L | Missense Mutation (SNP) | VAF 68/246 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.665); called by muse, mutect2, varscan2
- SRBD1 | c.1236G>C p.E412D | Missense Mutation (SNP) | VAF 29/215 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- SRBD1 | c.877G>A p.E293K | Missense Mutation (SNP) | VAF 23/202 reads (11%) | SIFT tolerated (0.59); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- SRRM2 | c.502C>T p.P168S | Missense Mutation (SNP) | VAF 37/94 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.813); called by muse, mutect2, varscan2
- SSTR1 | c.679A>G p.T227A | Missense Mutation (SNP) | VAF 124/334 reads (37%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- ST14 | c.1306A>T p.T436S | Missense Mutation (SNP) | VAF 166/682 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.675); called by muse, varscan2
- STIM1 | c.613+3G>C | Splice Region (SNP) | VAF 81/328 reads (25%) | called by muse, mutect2, varscan2
- STRN | c.2312G>T p.G771V | Missense Mutation (SNP) | VAF 49/168 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- STXBP2 | c.487G>T p.E163* | Nonsense Mutation (SNP) | VAF 128/524 reads (24%) | called by mutect2, varscan2
- STXBP5L | c.469C>G p.R157G | Missense Mutation (SNP) | VAF 28/130 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- STYXL2 | c.1074G>C p.Q358H | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- SYNE1 | c.13549G>T p.G4517C (on ENST00000367255 / NM_182961.4; = p.G4446C on NM_033071.3) | Missense Mutation (SNP) | VAF 168/483 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SYT4 | c.338G>C p.G113A | Missense Mutation (SNP) | VAF 67/313 reads (21%) | SIFT tolerated (0.77); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TBC1D4 | c.746G>A p.G249E | Missense Mutation (SNP) | VAF 148/419 reads (35%) | SIFT tolerated (0.29); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- TDRD6 | c.3415A>G p.I1139V | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- TENM3 | c.7569G>C p.K2523N | Missense Mutation (SNP) | VAF 81/377 reads (21%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- TEX15 | c.2230C>A p.Q744K (on ENST00000256246; = p.Q1127K on NM_001350162.2) | Missense Mutation (SNP) | VAF 38/156 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.592); called by muse, mutect2, varscan2
- TIMM17B | c.135_150del p.H46Vfs*5 | Frame Shift Del (DEL) | VAF 42/72 reads (58%) | called by mutect2, pindel
- TLN2 | c.7252G>A p.G2418R | Missense Mutation (SNP) | VAF 121/532 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TMC3 | c.973C>A p.L325M | Missense Mutation (SNP) | VAF 52/217 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- TMCC2 | c.1498G>C p.A500P | Missense Mutation (SNP) | VAF 85/275 reads (31%) | SIFT tolerated (0.57); PolyPhen benign (0.383); called by muse, mutect2, varscan2
- TMEM132C | c.3238G>T p.E1080* | Nonsense Mutation (SNP) | VAF 44/184 reads (24%) | called by muse, mutect2, varscan2
- TMEM38A | c.50C>G p.S17W | Missense Mutation (SNP) | VAF 63/379 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- TRAV9-2 | c.136G>T p.A46S | Missense Mutation (SNP) | VAF 60/355 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- TTC6 | c.704G>T p.G235V | Missense Mutation (SNP) | VAF 92/233 reads (39%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- TUBGCP4 | c.81A>T p.V27= | Splice Region (SNP) | VAF 33/130 reads (25%) | called by muse, mutect2, varscan2
- TXNRD3 | c.591G>T p.W197C | Missense Mutation (SNP) | VAF 42/168 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- UCN | c.91G>A p.A31T | Missense Mutation (SNP) | VAF 118/462 reads (26%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- UNC80 | c.4070G>T p.R1357L | Missense Mutation (SNP) | VAF 25/323 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- USP26 | c.2501G>T p.G834V | Missense Mutation (SNP) | VAF 145/282 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- VCAN | c.3984G>C p.E1328D | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- VPS13D | c.12197G>A p.G4066E | Missense Mutation (SNP) | VAF 37/168 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- WDR54 | c.801A>G p.L267= | Splice Region (SNP) | VAF 39/146 reads (27%) | called by muse, mutect2, varscan2
- XAB2 | c.208C>T p.L70F | Missense Mutation (SNP) | VAF 35/146 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- ZCCHC14 | c.1867A>G p.T623A (on ENST00000268616; = p.T760A on NM_015144.3) | Missense Mutation (SNP) | VAF 14/254 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.001); called by muse, mutect2
- ZNF133 | c.1370A>G p.Q457R (on ENST00000316358 / NM_001352454.2; = p.Q456R on NM_003434.7 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- ZNF155 | c.1196del p.S399Tfs*74 | Frame Shift Del (DEL) | VAF 74/277 reads (27%) | called by mutect2, pindel, varscan2
- ZNF257 | c.1323C>A p.N441K | Missense Mutation (SNP) | VAF 71/292 reads (24%) | SIFT tolerated (0.5); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF507 | c.1573G>T p.D525Y | Missense Mutation (SNP) | VAF 36/155 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.647); called by muse, mutect2, varscan2
- ZNF687 | c.3557C>A p.P1186H | Missense Mutation (SNP) | VAF 38/434 reads (9%) | SIFT tolerated (0.45); PolyPhen benign (0.133); called by muse, mutect2
- ZNF700 | c.884G>A p.R295K | Missense Mutation (SNP) | VAF 28/197 reads (14%) | SIFT tolerated (0.93); PolyPhen benign (0.266); called by muse, mutect2, varscan2
- ZNF720 | c.378G>T p.W126C | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.893); called by mutect2, varscan2
- ZNF729 | c.155T>A p.L52Q | Missense Mutation (SNP) | VAF 45/247 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- ZNF804A | c.2970G>T p.E990D | Missense Mutation (SNP) | VAF 61/225 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- ABCC6 | c.3042C>A p.A1014= | Silent (SNP) | VAF 8/237 reads (3%) | catalogued as COSV99229301; called by muse, mutect2
- ACTN2 | c.2181G>A p.L727= | Silent (SNP) | VAF 153/647 reads (24%) | called by muse, mutect2, varscan2
- ADAM11 | c.1938G>C p.L646= | Silent (SNP) | VAF 28/382 reads (7%) | catalogued as COSV52346424; called by muse, mutect2
- ADAMTSL3 | c.3927G>T p.V1309= | Silent (SNP) | VAF 76/295 reads (26%) | called by muse, mutect2, varscan2
- ADGRL3 | c.4422C>A p.T1474= (on ENST00000506720 / NM_001322402.2; = p.T1363= on NM_015236.6) | Silent (SNP) | VAF 100/454 reads (22%) | catalogued as rs1252506612; called by muse, mutect2, varscan2
- ANKRD30A | c.1251C>A p.I417= (on ENST00000611781; = p.I361= on NM_052997.2) | Silent (SNP) | VAF 82/365 reads (22%) | catalogued as COSV64610474; called by muse, mutect2, varscan2
- ANO5 | c.1866G>A p.Q622= | Silent (SNP) | VAF 14/320 reads (4%) | catalogued as COSV61084269; called by muse, mutect2
- APOB | c.96G>T p.L32= | Silent (SNP) | VAF 131/572 reads (23%) | called by muse, mutect2, varscan2
- ARL14EPL | c.183G>A p.Q61= | Silent (SNP) | VAF 37/210 reads (18%) | called by muse, mutect2, varscan2
- ATG9B | c.879G>A p.L293= | Silent (SNP) | VAF 49/166 reads (30%) | catalogued as COSV65059494; called by muse, mutect2, varscan2
- ATG9B | c.783G>T p.L261= | Silent (SNP) | VAF 106/395 reads (27%) | called by muse, mutect2, varscan2
- ATP4A | c.2376C>A p.T792= | Silent (SNP) | VAF 58/211 reads (27%) | called by muse, mutect2, varscan2
- BCO1 | c.99C>T p.L33= | Silent (SNP) | VAF 40/622 reads (6%) | called by muse, mutect2
- BICRA | c.4287C>T p.I1429= | Silent (SNP) | VAF 30/488 reads (6%) | catalogued as rs1401338314; called by muse, mutect2
- BTNL8 | c.180C>T p.F60= | Silent (SNP) | VAF 81/422 reads (19%) | called by muse, mutect2, varscan2
- CACNG2 | c.960C>A p.T320= | Silent (SNP) | VAF 42/189 reads (22%) | called by muse, mutect2, varscan2
- CBARP | c.1584C>A p.I528= | Silent (SNP) | VAF 23/102 reads (23%) | catalogued as COSV53070355; called by muse, mutect2, varscan2
- CDCP2 | c.306G>A p.L102= | Silent (SNP) | VAF 71/278 reads (26%) | catalogued as COSV61287092; called by muse, mutect2, varscan2
- CHRNA4 | c.765G>A p.L255= | Silent (SNP) | VAF 175/659 reads (27%) | called by muse, mutect2, varscan2
- CREB3L3 | c.309C>G p.R103= | Silent (SNP) | VAF 47/211 reads (22%) | called by muse, mutect2, varscan2
- DNAJC3 | c.249T>C p.A83= | Silent (SNP) | VAF 27/79 reads (34%) | called by muse, mutect2, varscan2
- DPEP3 | c.813G>A p.S271= | Silent (SNP) | VAF 22/334 reads (7%) | catalogued as rs773026799, COSV52051305; called by muse, mutect2
- DSC1 | c.60C>G p.L20= | Silent (SNP) | VAF 59/245 reads (24%) | catalogued as rs140443871; called by muse, mutect2, varscan2
- DSG1 | c.1422T>A p.T474= | Silent (SNP) | VAF 13/88 reads (15%) | called by muse, mutect2, varscan2
- ERMARD | c.654G>A p.L218= | Silent (SNP) | VAF 26/323 reads (8%) | catalogued as rs775664925; called by muse, mutect2
- EVC | c.2376G>T p.A792= | Silent (SNP) | VAF 188/680 reads (28%) | catalogued as COSV53829919; called by muse, mutect2, varscan2
- FAM47A | c.1710G>T p.S570= | Silent (SNP) | VAF 84/167 reads (50%) | catalogued as COSV60494418; called by muse, mutect2, varscan2
- FAM47A | c.1605C>A p.P535= | Silent (SNP) | VAF 24/56 reads (43%) | catalogued as rs769323473; called by muse, varscan2
- GALNS | c.21G>A p.A7= | Silent (SNP) | VAF 46/604 reads (8%) | called by muse, mutect2
- GPR132 | c.241C>T p.L81= | Silent (SNP) | VAF 50/186 reads (27%) | called by muse, mutect2, varscan2
- GPX6 | c.531T>C p.H177= | Silent (SNP) | VAF 98/605 reads (16%) | called by muse, mutect2, varscan2
- GRN | c.873A>C p.P291= | Silent (SNP) | VAF 128/510 reads (25%) | called by muse, mutect2, varscan2
- GTF3C3 | c.2211C>T p.V737= | Silent (SNP) | VAF 22/304 reads (7%) | called by muse, mutect2
- HECTD3 | c.942G>T p.G314= | Silent (SNP) | VAF 84/225 reads (37%) | called by muse, mutect2, varscan2
- HSPA6 | c.970C>A p.R324= | Silent (SNP) | VAF 162/801 reads (20%) | called by mutect2, varscan2
- HSPG2 | c.6147C>T p.S2049= | Silent (SNP) | VAF 58/256 reads (23%) | catalogued as rs1420628190; called by muse, mutect2, varscan2
- IL23R | c.117C>A p.A39= | Silent (SNP) | VAF 41/137 reads (30%) | called by muse, mutect2, varscan2
- INSYN2B | c.522C>T p.V174= | Silent (SNP) | VAF 43/166 reads (26%) | catalogued as rs1289931713; called by muse, mutect2, varscan2
- KANK1 | c.1113A>G p.T371= | Silent (SNP) | VAF 86/306 reads (28%) | catalogued as rs1317662576; called by muse, mutect2, varscan2
- KAT6A | c.5979C>T p.P1993= | Silent (SNP) | VAF 6/130 reads (5%) | called by muse, mutect2
- KIAA0753 | c.939C>G p.A313= | Silent (SNP) | VAF 76/232 reads (33%) | called by muse, mutect2, varscan2
- KLHDC7A | c.849C>A p.P283= | Silent (SNP) | VAF 37/172 reads (22%) | called by muse, mutect2, varscan2
- KLHL32 | c.615G>A p.E205= | Silent (SNP) | VAF 44/224 reads (20%) | called by muse, mutect2, varscan2
- KRT4 | c.1470C>A p.S490= | Silent (SNP) | VAF 108/415 reads (26%) | called by muse, mutect2, varscan2
- LMOD1 | c.1233C>G p.L411= | Silent (SNP) | VAF 33/387 reads (9%) | called by muse, mutect2
- LRIT1 | c.420C>T p.A140= | Silent (SNP) | VAF 134/512 reads (26%) | called by muse, mutect2, varscan2
- LSP1 | c.99C>T p.H33= | Silent (SNP) | VAF 20/279 reads (7%) | catalogued as rs150172209, COSV61132319; called by muse, mutect2
- LTBP1 | c.1854G>T p.R618= (on ENST00000404816 / NM_206943.4; = p.R292= on NM_000627.4) | Silent (SNP) | VAF 34/233 reads (15%) | called by muse, mutect2
- MADD | c.1137C>T p.A379= | Silent (SNP) | VAF 68/301 reads (23%) | called by muse, mutect2, varscan2
- MAML2 | c.1959A>G p.Q653= | Silent (SNP) | VAF 206/762 reads (27%) | catalogued as rs1179188122; called by mutect2, varscan2
- MINDY4B | c.576T>A p.A192= | Silent (SNP) | VAF 70/307 reads (23%) | called by muse, mutect2, varscan2
- MLX | c.630C>A p.I210= | Silent (SNP) | VAF 73/362 reads (20%) | called by muse, mutect2, varscan2
- MN1 | c.495C>T p.F165= | Silent (SNP) | VAF 56/312 reads (18%) | called by muse, mutect2, varscan2
- MS4A18 | c.405G>A p.T135= | Silent (SNP) | VAF 46/160 reads (29%) | catalogued as rs1038193602; called by muse, mutect2, varscan2
- MTMR12 | c.483C>G p.V161= | Silent (SNP) | VAF 13/71 reads (18%) | catalogued as rs1213433002; called by muse, mutect2
- MUC2 | c.633C>A p.P211= | Silent (SNP) | VAF 64/221 reads (29%) | called by muse, mutect2, varscan2
- MYT1 | c.2550C>T p.D850= | Silent (SNP) | VAF 14/402 reads (3%) | catalogued as rs767850867, COSV100115677; called by muse, mutect2
- NCAPD3 | c.1200C>T p.Y400= | Silent (SNP) | VAF 37/152 reads (24%) | called by muse, mutect2, varscan2
- NKX6-2 | c.282G>A p.G94= | Silent (SNP) | VAF 12/58 reads (21%) | called by muse, mutect2, varscan2
- NLRP4 | c.1290T>C p.P430= | Silent (SNP) | VAF 100/409 reads (24%) | catalogued as COSV56717597; called by muse, mutect2, varscan2
- NPAP1 | c.2640T>C p.D880= | Silent (SNP) | VAF 100/432 reads (23%) | catalogued as rs779167552; called by muse, mutect2, varscan2
- NPBWR2 | c.345G>T p.L115= | Silent (SNP) | VAF 95/387 reads (25%) | catalogued as rs777586340; called by muse, mutect2, varscan2
- OR14I1 | c.216C>A p.I72= | Silent (SNP) | VAF 29/126 reads (23%) | called by muse, mutect2, varscan2
- OR1S1 | c.444C>A p.L148= | Silent (SNP) | VAF 75/276 reads (27%) | catalogued as COSV58708424; called by muse, mutect2, varscan2
- OR2G6 | c.192C>T p.S64= | Silent (SNP) | VAF 113/413 reads (27%) | catalogued as COSV100598350; called by muse, mutect2, varscan2
- OR4K1 | c.690C>A p.S230= | Silent (SNP) | VAF 24/144 reads (17%) | called by muse, mutect2, varscan2
- OR8H1 | c.258G>T p.L86= | Silent (SNP) | VAF 65/217 reads (30%) | catalogued as rs931659901; called by muse, mutect2, varscan2
- PAK6 | c.39A>T p.S13= | Silent (SNP) | VAF 93/346 reads (27%) | called by muse, mutect2, varscan2
- PCDH18 | c.777C>T p.S259= | Silent (SNP) | VAF 26/127 reads (20%) | catalogued as rs765522617; called by muse, mutect2, varscan2
- PCDHA11 | c.1860G>T p.P620= | Silent (SNP) | VAF 103/359 reads (29%) | called by muse, mutect2, varscan2
- PCDHB3 | c.2322C>T p.F774= | Silent (SNP) | VAF 10/123 reads (8%) | catalogued as rs782811619, COSV50566253, COSV50575056; called by muse, mutect2, varscan2
- PEX7 | c.264C>T p.G88= | Silent (SNP) | VAF 35/615 reads (6%) | catalogued as rs775319689, COSV59251063; called by muse, mutect2
- PHF2 | c.687C>G p.A229= | Silent (SNP) | VAF 100/282 reads (35%) | called by muse, mutect2, varscan2
- PIBF1 | c.1887C>G p.L629= | Silent (SNP) | VAF 67/243 reads (28%) | called by muse, mutect2, varscan2
- PKD1L2 | c.132A>T p.P44= | Silent (SNP) | VAF 48/620 reads (8%) | called by muse, mutect2
- PLEKHH1 | c.1392C>G p.V464= | Silent (SNP) | VAF 26/443 reads (6%) | called by muse, mutect2
- PPFIA3 | c.2673A>T p.R891= | Silent (SNP) | VAF 106/460 reads (23%) | called by muse, mutect2, varscan2
- PRB4 | c.39G>C p.L13= | Silent (SNP) | VAF 129/700 reads (18%) | catalogued as rs1467491662; called by muse, mutect2, varscan2
- PRR23C | c.774C>G p.R258= | Silent (SNP) | VAF 18/72 reads (25%) | called by muse, varscan2
- PSMD11 | c.538C>T p.L180= | Silent (SNP) | VAF 62/341 reads (18%) | catalogued as COSV99912269; called by muse, mutect2, varscan2
- PTPDC1 | c.450T>C p.A150= (on ENST00000375360 / NM_177995.3; = p.A202= on NM_152422.4) | Silent (SNP) | VAF 55/135 reads (41%) | called by muse, mutect2, varscan2
- PTPRB | c.720G>A p.G240= | Silent (SNP) | VAF 123/570 reads (22%) | called by muse, mutect2, varscan2
- PTTG1IP | c.300C>T p.I100= | Silent (SNP) | VAF 39/127 reads (31%) | called by muse, varscan2
- PUF60 | c.999C>T p.I333= (on ENST00000526683 / NM_001362896.2; = p.I316= on NM_014281.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 38/219 reads (17%) | catalogued as rs1291042916, COSV57585119; called by muse, mutect2, varscan2
- RAMP3 | c.180C>A p.S60= | Silent (SNP) | VAF 40/204 reads (20%) | called by muse, mutect2, varscan2
- RIBC2 | c.1128A>G p.Q376= | Silent (SNP) | VAF 27/148 reads (18%) | catalogued as rs1028740834; called by muse, mutect2, varscan2
- RUNX1T1 | c.879C>G p.T293= (on ENST00000265814 / NM_001198628.1; = p.T266= on NM_004349.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 108/455 reads (24%) | catalogued as COSV56158146; called by muse, mutect2, varscan2
- RXFP2 | c.33C>T p.F11= | Silent (SNP) | VAF 14/245 reads (6%) | catalogued as rs769519937; called by muse, mutect2
- RYR2 | c.4641T>C p.A1547= | Silent (SNP) | VAF 34/185 reads (18%) | called by muse, mutect2, varscan2
- SALL3 | c.2706G>T p.S902= | Silent (SNP) | VAF 67/328 reads (20%) | catalogued as COSV73306114; called by muse, mutect2, varscan2
- SLC22A13 | c.1338C>T p.T446= | Silent (SNP) | VAF 23/104 reads (22%) | called by muse, mutect2, varscan2
- SLC46A1 | c.1071C>T p.L357= | Silent (SNP) | VAF 11/61 reads (18%) | called by muse, mutect2, varscan2
- SLC6A5 | c.345C>T p.G115= | Silent (SNP) | VAF 127/479 reads (27%) | called by muse, mutect2, varscan2
- SLC7A13 | c.273G>C p.T91= | Silent (SNP) | VAF 64/314 reads (20%) | catalogued as COSV52537724, COSV99878997; called by muse, mutect2, varscan2
- SOX6 | c.765G>A p.Q255= | Silent (SNP) | VAF 110/414 reads (27%) | called by muse, mutect2, varscan2
- STYK1 | c.714G>T p.A238= | Silent (SNP) | VAF 30/161 reads (19%) | catalogued as rs55732607; called by muse, mutect2, varscan2
- TAS1R2 | c.2079G>T p.V693= | Silent (SNP) | VAF 221/821 reads (27%) | called by muse, mutect2, varscan2
- TGIF2LY | c.432C>A p.A144= | Silent (SNP) | VAF 445/674 reads (66%) | called by muse, mutect2, varscan2
- TMPRSS15 | c.2586T>C p.I862= | Silent (SNP) | VAF 52/343 reads (15%) | called by muse, mutect2, varscan2
- TRIM15 | c.78G>T p.A26= | Silent (SNP) | VAF 186/430 reads (43%) | called by muse, mutect2, varscan2
- TRIM67 | c.2325G>C p.L775= | Silent (SNP) | VAF 34/207 reads (16%) | catalogued as COSV100792199; called by muse, mutect2, varscan2
- TTN | c.6297C>A p.V2099= (on ENST00000591111; = p.V2053= on NM_003319.4) | Silent (SNP) | VAF 29/461 reads (6%) | called by muse, mutect2
- UGT2B4 | c.1410T>C p.H470= | Silent (SNP) | VAF 133/539 reads (25%) | called by muse, mutect2, varscan2
- VCAN | c.6165T>C p.D2055= | Silent (SNP) | VAF 29/267 reads (11%) | catalogued as rs764642376; called by muse, mutect2, varscan2
- WNK2 | c.99G>C p.A33= | Silent (SNP) | VAF 29/83 reads (35%) | called by muse, mutect2, varscan2
- XIRP1 | c.3588T>C p.P1196= | Silent (SNP) | VAF 23/118 reads (19%) | called by muse, mutect2, varscan2
- ABCC5 | c.591+21C>T | Intron (SNP) | VAF 150/1368 reads (11%) | called by muse, mutect2, varscan2
- AC002059.3 | chr22:29419244 C>A | 3'Flank (SNP) | VAF 45/236 reads (19%) | called by muse, mutect2, varscan2
- AC022148.1 | n.294C>A | RNA (SNP) | VAF 33/121 reads (27%) | called by muse, mutect2
- AK2 | c.*3868A>T | 3'UTR (SNP) | VAF 68/292 reads (23%) | called by muse, mutect2, varscan2
- ANK2 | c.85-57081C>A | Intron (SNP) | VAF 79/306 reads (26%) | called by muse, mutect2, varscan2
- AP000769.5 | chr11:65498989 T>C | 5'Flank (SNP) | VAF 50/249 reads (20%) | catalogued as rs754397792; called by muse, mutect2, varscan2
- ATP1A3 | c.*124C>T | 3'UTR (SNP) | VAF 32/97 reads (33%) | called by muse, mutect2, varscan2
- BHLHE40-AS1 | n.883C>A | RNA (SNP) | VAF 58/340 reads (17%) | called by muse, mutect2
- C10orf143 | c.69+3661dup | Intron (INS) | VAF 41/206 reads (20%) | called by mutect2, pindel, varscan2
- CCDC110 | c.10+85C>G | Intron (SNP) | VAF 72/347 reads (21%) | called by muse, mutect2, varscan2
- CCSER1 | c.2217+239224G>A | Intron (SNP) | VAF 49/146 reads (34%) | called by muse, mutect2, varscan2
- CDK2AP2 | c.*13C>G | 3'UTR (SNP) | VAF 18/220 reads (8%) | called by muse, mutect2
- CDKN3 | c.-30G>A | 5'UTR (SNP) | VAF 13/83 reads (16%) | catalogued as rs750303171; called by muse, mutect2, varscan2
- CHD8 | c.5051+529G>C | Intron (SNP) | VAF 17/86 reads (20%) | called by muse, mutect2, varscan2
- CRMP1 | chr4:5892820 G>A | 5'Flank (SNP) | VAF 8/172 reads (5%) | called by muse, mutect2
- CYP4F24P | n.495C>T | RNA (SNP) | VAF 11/184 reads (6%) | called by muse, mutect2
- D2HGDH | c.1141-697G>T | Intron (SNP) | VAF 114/317 reads (36%) | called by muse, mutect2, varscan2
- DCHS2 | n.897A>G | RNA (SNP) | VAF 44/143 reads (31%) | called by muse, mutect2, varscan2
- EEF1B2 | c.203+130C>T | Intron (SNP) | VAF 19/188 reads (10%) | catalogued as rs1329808215; called by muse, mutect2
- EIF5AL1 | chr10:79507627 C>T | 5'Flank (SNP) | VAF 278/1162 reads (24%) | catalogued as rs1431605768; called by muse, mutect2, varscan2
- EMD | c.266-36G>A | Intron (SNP) | VAF 142/261 reads (54%) | called by muse, mutect2, varscan2
- FAM177A1 | c.-28-12C>T | Intron (SNP) | VAF 52/201 reads (26%) | catalogued as rs767636712; called by muse, mutect2, varscan2
- FUNDC2P2 | n.145G>T | RNA (SNP) | VAF 24/104 reads (23%) | called by muse, mutect2, varscan2
- GOLGA8J | c.591+281G>T | Intron (SNP) | VAF 76/422 reads (18%) | called by muse, mutect2, varscan2
- GYPA | c.-50C>A | 5'UTR (SNP) | VAF 25/148 reads (17%) | called by muse, mutect2, varscan2
- HDAC6 | c.999+24G>T | Intron (SNP) | VAF 75/142 reads (53%) | catalogued as COSV100491173; called by muse, mutect2, varscan2
- HGF | c.89-38C>A | Intron (SNP) | VAF 14/80 reads (18%) | catalogued as rs895852815; called by muse, mutect2
- KIF16B | c.3498+2838G>T | Intron (SNP) | VAF 77/242 reads (32%) | catalogued as COSV61712130; called by muse, mutect2, varscan2
- LINC00692 | n.507C>A | RNA (SNP) | VAF 33/164 reads (20%) | called by muse, mutect2, varscan2
- LRRIQ3 | c.707+11229G>T | Intron (SNP) | VAF 6/67 reads (9%) | called by muse, mutect2, varscan2
- MAPKAPK5 | c.36+21C>A | Intron (SNP) | VAF 13/34 reads (38%) | catalogued as rs1197590047; called by muse, mutect2, varscan2
- MAZ | c.*185_*188del | 3'UTR (DEL) | VAF 440/1822 reads (24%) | called by mutect2, pindel, varscan2
- NDUFAF6 | c.298-1425G>T | Intron (SNP) | VAF 27/152 reads (18%) | catalogued as rs1272836416; called by muse, mutect2, varscan2
- NETO1 | c.29-354G>T | Intron (SNP) | VAF 36/210 reads (17%) | called by muse, mutect2, varscan2
- NRP1 | c.1864+90C>T | Intron (SNP) | VAF 60/266 reads (23%) | called by muse, mutect2, varscan2
- OR56B3P | n.723C>G | RNA (SNP) | VAF 58/300 reads (19%) | called by muse, mutect2, varscan2
- OR8H1 | c.*19T>A | 3'UTR (SNP) | VAF 26/97 reads (27%) | called by muse, mutect2, varscan2
- PLEKHB2 | c.-93G>C | 5'UTR (SNP) | VAF 69/247 reads (28%) | catalogued as COSV52176023; called by muse, mutect2, varscan2
- PLEKHG3 | c.*6040dup | 3'UTR (INS) | VAF 69/379 reads (18%) | catalogued as rs1336271772; called by mutect2, pindel, varscan2
- POTEG | c.811-1189C>A | Intron (SNP) | VAF 33/540 reads (6%) | called by muse, mutect2
- PSMD5 | c.1006+79T>G | Intron (SNP) | VAF 41/139 reads (29%) | called by muse, mutect2, varscan2
- RN7SL495P | chr15:22610694 A>T | 5'Flank (SNP) | VAF 101/404 reads (25%) | called by muse, mutect2, varscan2
- RNFT2 | c.*2239G>A | 3'UTR (SNP) | VAF 14/50 reads (28%) | called by muse, mutect2
- RPGRIP1L | c.230+706G>T | Intron (SNP) | VAF 35/104 reads (34%) | called by muse, mutect2, varscan2
- RPGRIP1L | c.230+705G>T | Intron (SNP) | VAF 35/105 reads (33%) | called by muse, mutect2, varscan2
- SLC4A11 | c.137-12G>T | Intron (SNP) | VAF 112/403 reads (28%) | called by muse, mutect2, varscan2
- SNORD115-25 | n.61C>T | RNA (SNP) | VAF 90/426 reads (21%) | catalogued as rs1293697636; called by muse, mutect2, varscan2
- ST8SIA5 | c.132-16761G>T | Intron (SNP) | VAF 101/420 reads (24%) | catalogued as rs1408767395; called by muse, mutect2, varscan2
- STX11 | c.*40G>A | 3'UTR (SNP) | VAF 16/326 reads (5%) | called by muse, mutect2
- SYNE1 | c.3027+18G>T | Intron (SNP) | VAF 53/351 reads (15%) | called by muse, mutect2, varscan2
- TDO2 | c.*5G>A | 3'UTR (SNP) | VAF 23/176 reads (13%) | catalogued as rs373716255; called by muse, mutect2, varscan2
- TMEM135 | c.*6988G>C | 3'UTR (SNP) | VAF 17/234 reads (7%) | called by muse, mutect2
- TRPM8 | c.2761+76C>T | Intron (SNP) | VAF 61/143 reads (43%) | catalogued as rs1354322282; called by muse, mutect2, varscan2
- TSN | c.160+109A>C | Intron (SNP) | VAF 27/100 reads (27%) | called by muse, mutect2, varscan2
- Unknown | chr11:119498692 G>T | IGR (SNP) | VAF 215/665 reads (32%) | called by muse, mutect2, varscan2
- XIST | n.7811C>A | RNA (SNP) | VAF 64/124 reads (52%) | called by muse, mutect2, varscan2
- ZC3HAV1 | c.1471+203G>T | Intron (SNP) | VAF 102/395 reads (26%) | called by muse, mutect2, varscan2
- ZNF875 | c.314-2498C>T | Intron (SNP) | VAF 6/15 reads (40%) | called by muse, mutect2, varscan2
- ZNF99 | c.*186C>A | 3'UTR (SNP) | VAF 32/170 reads (19%) | catalogued as COSV101233910; called by muse, mutect2, varscan2
